Somatic mutation profile of tumor specimen TCGA-EL-A3H2-01A (aliquot TCGA-EL-A3H2-01A-11D-A20C-08) from TCGA case TCGA-EL-A3H2, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 58.2 years (21,266 days).
Specimen TCGA-EL-A3H2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ece492d4-724b-4e0d-bb8a-555327a52ca3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3H2-11A (Solid Tissue Normal), aliquot TCGA-EL-A3H2-11A-11D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abb0b3d5-a073-4728-ade4-dc2e1bf0fcdf

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EFS | c.1549G>T p.A517S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.074); catalogued as COSV52835360, COSV99249116; called by muse, mutect2, varscan2
- STAT5B | c.2129+1G>C p.X710_splice | Splice Site (SNP) | VAF 10/322 reads (3%) | catalogued as COSV53181925; called by muse, mutect2
- TMEM67 | c.1990C>A p.P664T | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60038103, COSV60038821; called by muse, mutect2, varscan2
- C10orf71 | c.1069del p.Q357Rfs*42 | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | called by mutect2, pindel, varscan2
- CRAT | c.330C>T p.Y110= | Silent (SNP) | VAF 3/52 reads (6%) | catalogued as COSV58876751; called by muse, mutect2
- DSG4 | c.1764T>C p.D588= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs769113109, COSV57390543; called by muse, mutect2
- ZNF169 | c.1497G>T p.S499= | Silent (SNP) | VAF 52/107 reads (49%) | catalogued as COSV61763938, COSV61767381; called by muse, mutect2, varscan2
